CCDI case PBCNAR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ed3cbf37-0d4f-47cd-8930-5aa3b4d3fd30

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,956 days).

Biospecimens (4 samples)
- Samples 0DVM0N, 0DVM1I (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVM1U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWI1D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
